Surgical pathology report (de-identified scan), TCGA case TCGA-HI-7169, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-HI-7169-01A (Primary Tumor).

[page 1 of 2]
Sex: M

TCGA-HI-7169

Source of Specimen(s):

- 1: left posterior lateral margin
- 2: Prostate and Seminal Vessicles
- 3: right pelvic lymph nodes
- 4: left pelvic lymph nodes

Gross Description:

Received in four parts.

Source of Tissue: 1. Labeled # 1, "left posterior lateral margin"

Gross Description: Received fresh in a container labeled, left posterior lateral margin". It consists of two fragments of dark red fibrofatty tissue measuring 0.7 and 0.9 cm. They are unremarkable and submitted in toto in 1A.

Source of Tissue: 2. Labeled # 2, "prostate and seminal vesicles"

Gross Description: Received fresh in a container labeled ", prostate and seminal vesicles". It consists of a radical prostate resection weighing 35-grams and measuring 3.5 x 4.0 x 3.4 cm. The capsule is intact and a probe inserts easily through the prostatic urethra. The right side is inked black and left side blue. Sections disclose a yellowish tan periphery and centrally the parenchyma is firm and white, suspicious for lesion. There is a small amount of prostatic concretions noted. The right seminal vesicle measures 2.0 x 1.2 x 0.7 cm and left measures 3.0 x 1.5 x 1.0 cm. Both are unremarkable. The right and left vas deferens stumps measure 2.5 x 0.6 cm. Representative sections are submitted in 2A-N.

Designation of Sections: 2A-2B- apex, 2C-2D- base, 2E-2H- right side of prostate gland [E- anterior, F- mid, G&H- superior posterior], 2I-2L- left side of prostate gland [I- anterior, J- mid, K&L- superior posterior], 2M- right vas deferens and seminal vesicle, 2N- left vas deferens and seminal vesicle

Source of Tissue: 3. Labeled # 3, "right pelvic lymph nodes"

Gross Description: Received fresh in a container labeled, right pelvic lymph nodes". It consists of multiple fragments of fibroadipose tissue measuring collectively 4.5 x 3.5 x 2.0 cm. The tissue is dissected to disclose two potential lymph nodes measuring respectively 0.9 x 0.5 x 0.5 and 2.0 x 1.0 x 1.0 cm. Both nodes are fatty. All of the nodal tissue is submitted in 3A and the rest of the fat in 3B.

[page 2 of 2]
Source of Tissue: 4. Labeled # 4, "left pelvic lymph nodes"

Gross Description: Received fresh in a container labeled, left pelvic lymph nodes". It consists of some fibroadipose tissue measuring collectively 4.0 x 3.0 x 1.5 cm. The tissue is dissected disclosing two firm tan lymph nodes measuring 1.0 and 1.4 cm respectively. All of the nodal tissue is submitted in 4A and the remaining fat in 4B.

Final Diagnosis:

1. Left posterior lateral margin, excision:

- No tumor seen. No prostatic tissue seen.

2. Prostate and seminal vesicles, radical prostatectomy:

- Prostatic adenocarcinoma, Gleason's score 7 (3+4), involving both right and left lobes (right>left); extraprostatic extension is seen (the right mid on slide 2F and the right apex on slide 2B); see note.
- Tumor is present at the inked right apex margin.
- The base and other radial margins with no tumor seen.
- The seminal vesicles with no tumor seen.

Note: The tumor is seen on most of the sections of the right side of the prostate (including the right apex).

3. Right pelvic lymph nodes, excision:

- No tumor seen in two lymph nodes (0/2).

4. Left pelvic lymph nodes, excision:

- No tumor seen in two lymph nodes (0/2).

Source: NCI Genomic Data Commons file 0cb69023-3df7-493b-a44f-2071150e38fc (TCGA-HI-7169.ED386BC1-82A8-489E-81E0-53A93325A48E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).